Somatic mutation profile of tumor specimen TCGA-MH-A562-01A (aliquot TCGA-MH-A562-01A-11D-A26P-10) from TCGA case TCGA-MH-A562, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 57.3 years (20,933 days).
Specimen TCGA-MH-A562-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc90d468-7c8e-494f-9b64-374ce8b96ea9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MH-A562-10A (Blood Derived Normal), aliquot TCGA-MH-A562-10A-01D-A26P-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aadc7c4b-049e-4e32-9870-c9d9e6c2eb8a

The open-access MAF lists 71 somatic variants for this specimen: 45 protein-altering or splice-affecting, 22 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 22, Frame Shift Del 6, 3'UTR 2, 3'Flank 1, Intron 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD16A | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs762888798, COSV65452588; called by muse, mutect2, varscan2
- ADAMTS5 | c.1781G>C p.C594S | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53185115; called by muse, mutect2, varscan2
- ADD1 | c.326C>A p.A109D | Missense Mutation (SNP) | VAF 82/200 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV53274248; called by muse, mutect2, varscan2
- ASB16 | c.1244C>G p.A415G | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs192236945, COSV53236445; called by muse, mutect2
- CAMTA2 | c.1954A>C p.M652L | Missense Mutation (SNP) | VAF 85/180 reads (47%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.448); catalogued as COSV61838176; called by muse, mutect2, varscan2
- CARHSP1 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.974); catalogued as COSV60683549, COSV60684581; called by muse, mutect2, varscan2
- FAT1 | c.3013G>A p.D1005N | Missense Mutation (SNP) | VAF 88/251 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV71675975; called by muse, mutect2, varscan2
- GLI1 | c.1054C>A p.Q352K | Missense Mutation (SNP) | VAF 87/344 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV57367248; called by muse, mutect2, varscan2
- HNRNPU | c.2050T>C p.Y684H (on ENST00000283179; = p.Y746H on NM_004501.3) | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.899); catalogued as COSV51694210; called by muse, mutect2, varscan2
- IGDCC4 | c.2196G>C p.K732N | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as COSV61539191; called by muse, mutect2, varscan2
- IGSF3 | c.3335G>C p.S1112T (on ENST00000369486 / NM_001007237.3; = p.S1132T on NM_001542.4) | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as COSV59598508; called by muse, mutect2, varscan2
- IP6K2 | c.478T>C p.Y160H | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.34); catalogued as rs1341183905, COSV60795285; called by muse, mutect2, varscan2
- KCNA4 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as rs1323104794, COSV60255883; called by muse, mutect2, varscan2
- KLHDC9 | c.661G>A p.G221R | Missense Mutation (SNP) | VAF 63/211 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV63510580; called by muse, mutect2, varscan2
- MTREX | c.583A>G p.S195G | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57930109; called by muse, mutect2, varscan2
- NXPH3 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 93/154 reads (60%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.834); catalogued as COSV60872681; called by muse, mutect2, varscan2
- OPN4 | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1382220358, COSV54119527, COSV54120009; called by muse, mutect2, varscan2
- OR5H2 | c.151A>C p.I51L | Missense Mutation (SNP) | VAF 90/256 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as COSV62351862; called by muse, mutect2, varscan2
- OSR1 | c.673C>T p.H225Y | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV55346503; called by muse, mutect2
- P2RX2 | c.890C>T p.S297L (on ENST00000343948 / NM_170683.4; = p.S225L on NM_012226.5) | Missense Mutation (SNP) | VAF 11/181 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV57690386; called by muse, mutect2
- PHACTR1 | c.1543G>C p.E515Q | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.952); catalogued as COSV60681235; called by muse, mutect2, varscan2
- POU4F1 | c.1211G>T p.C404F | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65885071; called by muse, mutect2, varscan2
- PSG5 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 76/242 reads (31%) | catalogued as COSV61653955; called by muse, mutect2, varscan2
- PTCHD1 | c.1690A>G p.I564V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV65062680; called by mutect2, varscan2
- RANBP10 | c.1487C>A p.P496H | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.02); catalogued as COSV58161158; called by muse, mutect2, varscan2
- SALL1 | c.3649T>G p.F1217V | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51764494; called by muse, mutect2, varscan2
- SCRN2 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 101/205 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1369950760, COSV51637343; called by muse, mutect2, varscan2
- SETD1A | c.49T>C p.W17R | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52692350; called by muse, mutect2, varscan2
- SEZ6L | c.2753G>A p.G918E | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50686376; called by muse, mutect2, varscan2
- SLC34A2 | c.1453C>G p.L485V | Missense Mutation (SNP) | VAF 75/196 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.458); catalogued as COSV65943142; called by muse, mutect2, varscan2
- SLC5A10 | c.947T>A p.I316N | Missense Mutation (SNP) | VAF 70/128 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV58761979; called by muse, mutect2, varscan2
- STXBP5 | c.1966G>C p.D656H | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51658093; called by muse, mutect2, varscan2
- TNK2 | c.131A>G p.E44G | Missense Mutation (SNP) | VAF 8/252 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57375820; called by muse, mutect2
- TPRA1 | c.1061C>G p.P354R | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56161851; called by muse, mutect2, varscan2
- UNC80 | c.3473T>G p.F1158C | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.518); catalogued as rs1490443462, COSV55905832; called by muse, mutect2, varscan2
- WDR91 | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 178/477 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.199); catalogued as COSV100615775, COSV60371854; called by muse, mutect2, varscan2
- ZFP57 | c.266A>G p.H89R | Missense Mutation (SNP) | VAF 82/198 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.047); catalogued as rs1444492534, COSV65306987; called by muse, mutect2, varscan2
- ARRDC3 | c.534_538del p.E178Dfs*19 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by pindel, varscan2
- EZH1 | c.40_43del p.Y14Gfs*5 | Frame Shift Del (DEL) | VAF 21/81 reads (26%) | called by mutect2, pindel, varscan2
- GSTM4 | c.391C>A p.L131I | Missense Mutation (SNP) | VAF 91/283 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MPHOSPH10 | c.1320_1326del p.V442Kfs*15 | Frame Shift Del (DEL) | VAF 26/153 reads (17%) | called by mutect2, pindel, varscan2
- MYPOP | c.796del p.Q266Sfs*22 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- PLS3 | c.1337dup p.N446Kfs*2 | Frame Shift Ins (INS) | VAF 80/152 reads (53%) | called by mutect2, pindel, varscan2
- RAD51AP2 | c.3331del p.S1111Vfs*37 | Frame Shift Del (DEL) | VAF 15/97 reads (15%) | called by mutect2, pindel, varscan2
- TRMT10C | c.539del p.L180Yfs*10 | Frame Shift Del (DEL) | VAF 15/46 reads (33%) | called by mutect2, pindel, varscan2
- API5 | c.984A>T p.G328= | Silent (SNP) | VAF 67/211 reads (32%) | catalogued as COSV66635110; called by muse, mutect2, varscan2
- BCL2L1 | c.573T>C p.F191= (on ENST00000307677 / NM_001317919.2; = p.F128= on NM_001191.4) | Silent (SNP) | VAF 67/129 reads (52%) | catalogued as rs755249882, COSV56969371; called by muse, mutect2, varscan2
- BTNL8 | c.600C>T p.N200= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as rs377605273; called by muse, mutect2, varscan2
- CAPN12 | c.1602C>A p.I534= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV53150673; called by muse, mutect2, varscan2
- CDK10 | c.660C>T p.I220= (on ENST00000353379 / NM_052988.5; = p.I149= on NM_052987.4) | Silent (SNP) | VAF 59/147 reads (40%) | catalogued as rs762300822, COSV57047013; called by muse, mutect2, varscan2
- CWH43 | c.1410T>G p.S470= | Silent (SNP) | VAF 38/106 reads (36%) | catalogued as rs755901661, COSV56943971; called by muse, mutect2, varscan2
- CYP4F22 | c.891C>T p.A297= | Silent (SNP) | VAF 31/123 reads (25%) | catalogued as COSV54111834; called by muse, mutect2, varscan2
- IL4R | c.1461G>A p.T487= | Silent (SNP) | VAF 40/114 reads (35%) | catalogued as rs1389225742, COSV50171226; called by muse, mutect2
- LILRB3 | c.1842C>A p.T614= (on ENST00000346401; = p.T602= on NM_006864.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 95/180 reads (53%) | catalogued as COSV54446536; called by muse, mutect2, varscan2
- MCAM | c.96G>A p.A32= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs558009680, COSV50685170; called by mutect2, varscan2
- NRP1 | c.819C>T p.F273= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV99588940; called by muse, mutect2
- NRXN2 | c.1857T>A p.I619= | Silent (SNP) | VAF 66/158 reads (42%) | catalogued as COSV55462936; called by muse, mutect2, varscan2
- PEAK1 | c.1656T>A p.T552= | Silent (SNP) | VAF 34/106 reads (32%) | catalogued as COSV56942952; called by muse, mutect2, varscan2
- PRKG2 | c.1434T>A p.A478= | Silent (SNP) | VAF 37/148 reads (25%) | catalogued as COSV52331700; called by muse, mutect2, varscan2
- SCN4A | c.837G>A p.K279= | Silent (SNP) | VAF 112/470 reads (24%) | catalogued as rs758801697, COSV71129037; called by muse, varscan2
- SCN4A | c.834G>A p.Q278= | Silent (SNP) | VAF 109/462 reads (24%) | catalogued as COSV71129041; called by muse, varscan2
- SLC24A1 | c.2322A>G p.G774= | Silent (SNP) | VAF 64/204 reads (31%) | catalogued as COSV56054050; called by muse, varscan2
- SLC26A1 | c.2037T>C p.S679= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as rs757123282, COSV56106404; called by muse, mutect2, varscan2
- URB2 | c.1461G>A p.Q487= | Silent (SNP) | VAF 51/109 reads (47%) | catalogued as rs1315529368, COSV51044567; called by muse, mutect2, varscan2
- VCAN | c.1560G>A p.L520= | Silent (SNP) | VAF 41/127 reads (32%) | catalogued as COSV54106346, COSV54116402; called by muse, mutect2, varscan2
- ZFHX4 | c.111G>A p.G37= | Silent (SNP) | VAF 81/256 reads (32%) | catalogued as COSV51495514; called by muse, mutect2, varscan2
- ZMPSTE24 | c.90G>C p.V30= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as COSV65640212; called by muse, mutect2, varscan2
- NT5C2 | c.389+347A>G | Intron (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- SRSF8 | c.*403A>C | 3'UTR (SNP) | VAF 16/59 reads (27%) | catalogued as COSV101475805; called by muse, mutect2, varscan2
- ZBTB43 | chr9:126838005 del TAGG | 3'Flank (DEL) | VAF 25/102 reads (25%) | called by mutect2, pindel, varscan2
- ZNF345 | c.*537_*562del | 3'UTR (DEL) | VAF 24/78 reads (31%) | called by mutect2, varscan2
